Surgical pathology report (de-identified scan), TCGA case TCGA-J7-8537, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site ILSBio, specimen TCGA-J7-8537-01A (Primary Tumor).

[page 1 of 5]
Clinical Information

HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain ; hard urination ; fever

Symptoms: Hematuria ; Weight loss

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

Menopausal Status ☒ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal		Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other: _____	☐ Hormone Replacement Therapy: _____
--	--	--	--

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	x A tumour was found in the left kidney	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Location of Suspected Involved L	Suspected Distant Metastasis
Clinical Staging	
T3 N1 M0	Stage: IV

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Resection of the left kidney		
Primary Tumor		
Organ	Detailed Location	Size
left kidney tumor		3.5 x 3 x 2 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T3 N1 M0 Stage: IV		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
left kidney Tumor	3.5 x 3 x 2 cm		4 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₃	N ₁	M ₀	Stage: IV

Notes:

[page 5 of 5]
CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		X	Streaming		
Mosaic	X		Storiform		
Necrosis	X		Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion	X	X	Cystic Degeneration		
Clusterized		X	Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamous Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation	X		Myoblast			Plasma Cell		

Otherwise Specified:

D₁ 75% D₂ 75% D₃ 20% D₄ 70% Necrosis 3%

2. Cellular Differentiation:

Well	Moderately	Poor
	X	

3. Nuclear Atypia:

Nuclear Appearance		0	I	II	III
Aniso Nucleosis				X	
Hyperchromatism			X		
Nucleolar Prominent			X		
Multinucleated Giant Cell				X	
Mitotic Activity				X	
Nuclear Grade				X	

Histological Diagnosis: Papillary renal cell Carcinoma, G₂

Comments: M₁, M₂: Carcinoma Metastasized to L/V.

Source: NCI Genomic Data Commons file 73c15595-153e-43a9-b4b5-b2406952c0ff (TCGA-J7-8537.F002F403-3255-43BB-9A47-A198CD758E68.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).